CPTAC case C3L-01887 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8b0ed6bd-7eea-4a99-b901-a0a8a858d97a

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1968; Vital status: Dead; Days to death: 1,703 days (4.7 years); Year of death: 2022; Cause of death: Cancer Related; Country of birth: United States.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Age at diagnosis: 49.0 years (17,887 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 1,703 days (4.7 years); Progression or recurrence: yes; Days to recurrence: 1,468 days (4.0 years); Days to last follow up: 1,622 days (4.4 years).
   Pathology details: Greatest tumor dimension: 3.5 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (6 entries)
- Days to follow up: 348 days; Disease response: Tumor Free.
- Days to follow up: 692 days (1.9 years); Disease response: Tumor Free.
- Days to follow up: 1,075 days (2.9 years); Disease response: Tumor Free.
- Days to follow up: 1,408 days (3.9 years); Disease response: Tumor Free.
- Days to follow up: 1,408 days (3.9 years); Disease response: Complete Response.
- Days to follow up: 1,622 days (4.4 years); Disease response: With Tumor.

Other clinical attributes
- Weight: 95.2 kg; Height: 177.8 cm; BMI: 30.11.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01887-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Temporal Cortex; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -1 day; Initial weight: 235 mg; Time between excision and freezing: 19 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01887-21: Section location: Left Temporal; Percent tumor nuclei: 80; Percent necrosis: 30.
- Sample C3L-01887-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -1 day; Method of sample procurement: Blood Draw.
